Somatic mutation profile of tumor specimen ALCH-B3CY-TTP1-A (aliquot ALCH-B3CY-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3CY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,891 days).
Specimen ALCH-B3CY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4330af84-a799-407f-a1bc-1ce07687f973.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3CY-NB1-A (Blood Derived Normal), aliquot ALCH-B3CY-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cffda515-c8d2-4f17-86d4-ee3928dd390b

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Intron 4, In Frame Del 2, 3'Flank 1, 5'UTR 1, In Frame Ins 1, RNA 1, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 76/313 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 39/167 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID3B | c.36_41del p.Q14_Q15del | In Frame Del (DEL) | VAF 4/38 reads (11%) | catalogued as rs767879408; called by mutect2, pindel
- CCDC60 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV59544782; called by muse, mutect2, varscan2
- CLDN15 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs765578247; called by muse, mutect2, varscan2
- FLNC | c.7123G>A p.V2375I | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.529); catalogued as rs768941858, COSV57962607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC66 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs1189619671; called by muse, mutect2, varscan2
- MYO7B | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.821); catalogued as rs773945125; called by muse, mutect2, varscan2
- NLRP4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs370421219; called by muse, mutect2, varscan2
- PCDH10 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.834); catalogued as COSV52086654, COSV52088666; called by muse, mutect2, varscan2
- RIMBP2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113895223, COSV55468396; called by mutect2, varscan2
- SCN10A | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs267599804, COSV71860817; called by muse, mutect2, varscan2
- SLC26A3 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs776888978, COSV60639399; called by muse, mutect2, varscan2
- TTN | c.27311C>T p.T9104M (on ENST00000591111; = p.T8177M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | PolyPhen benign (0.051); catalogued as rs375209383; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZNF681 | c.504dup p.P169Tfs*3 | Frame Shift Ins (INS) | VAF 13/81 reads (16%) | catalogued as rs745843775; called by mutect2, varscan2
- ACSM2B | c.1047G>A p.W349* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- ACTN3 | c.492G>T p.L164F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP77 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CHM | c.932A>G p.E311G | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CMBL | c.256_257insCGG p.W85_D86insA | In Frame Ins (INS) | VAF 22/155 reads (14%) | called by mutect2, pindel, varscan2
- COL27A1 | c.3674G>T p.G1225V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- DUOX2 | c.2443del p.L815Wfs*38 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- F2R | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GC | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- KIAA1210 | c.3004G>T p.G1002C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- KIFC1 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LONRF1 | c.1052C>G p.P351R | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRP1 | c.2333C>G p.T778S | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MAF | c.166T>G p.S56A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYH8 | c.1574A>G p.E525G | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PLXNA3 | c.3163C>T p.R1055W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- R3HDM1 | c.1153A>C p.I385L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- RALGAPB | c.1567A>T p.I523F | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RNF43 | c.36_62del p.W13_L21del | In Frame Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- RPH3A | c.548A>T p.E183V (on ENST00000389385 / NM_001143854.2; = p.E179V on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SLC25A20 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ST6GALNAC3 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TNK1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, varscan2
- WDFY4 | c.4003A>T p.N1335Y | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASXL2 | c.408G>A p.S136= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1232981139, COSV55464605; called by muse, mutect2, varscan2
- FAM43B | c.477C>T p.F159= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, varscan2
- MRPS18C | c.6C>T p.A2= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs760876096, COSV55026633; called by mutect2, varscan2
- NALCN | c.75G>A p.S25= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs374635988, COSV51922893; called by muse, mutect2, varscan2
- NRXN3 | c.2613C>T p.D871= (on ENST00000335750 / NM_001330195.2; = p.D498= on NM_004796.6) | Silent (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- PTK6 | c.432C>T p.S144= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1569012646; called by muse, mutect2, varscan2
- RUFY1 | c.2061G>A p.K687= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- SLC24A2 | c.606C>T p.N202= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs147285634, COSV53864646; called by muse, mutect2, varscan2
- UNC5A | c.1893G>A p.Q631= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, varscan2
- C3orf33 | c.114+434T>G | Intron (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- GRK4 | c.-41C>T | 5'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- GUSBP10 | n.252G>A | RNA (SNP) | VAF 12/55 reads (22%) | catalogued as rs763473917; called by muse, mutect2, varscan2
- ITGB3BP | c.484+70T>A | Intron (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+620A>C | Intron (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- NHS | c.566-52199A>T | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928655 G>A | 3'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
